Gene-level copy-number profile of tumor specimen TCGA-CD-5804-01A from TCGA case TCGA-CD-5804, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CD-5804-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.abe6185b-9f9b-4a61-bd71-9ad49a14760a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-5804-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e5e8607-694d-46a1-b244-0ad08f256221

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 5,135; copy number 2: 38,450; copy number 3: 12,445; copy number 4: 1,903; copy number 5: 1,080; copy number 6: 324; copy number 7: 112; copy number 8: 81; copy number 11: 109; copy number 13: 30; copy number 14: 33; copy number 15: 5; copy number 17: 3; copy number 19: 7; copy number 24: 1; copy number 27: 4; copy number 29: 4; copy number 32: 4; copy number 35: 3; copy number 39: 12; copy number 53: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-5804-01A-12D-2052-01): tumor purity 0.43, ploidy 2.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:18,704,433–21,779,522, 24 genes: LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1.
- chr8:150,584–738,106, 19 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1.
- chr8:738,548–893,112, 2 genes: AC100797.4, AC026950.2.
- chr8:2,648,075–2,877,916, 3 genes (within-gene range 0–1): AC246817.2, AC246817.1, AC115485.1.
- chr20:14,884,250–15,280,873, 5 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,824 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–120,914,238, 55 genes, copy number 7–24: TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr1:120,942,600–120,942,763, 1 gene, copy number 7: RNVU1-4.
- chr2:94,725,674–95,547,545, 53 genes, copy number 11: CNN2P11, GXYLT1P7, CNN2P8, AC073464.2, CYP4F32P, AC073464.1, SNX18P14, ANKRD20A8P, RNU6-1320P, SOWAHCP5, AC097374.1, TEKT4, MTCO1P48, MTCO3P45, RPS24P6, AC103563.3, AC103563.4, AC103563.5, AC103563.1, AC103563.6, AC103563.8, RN7SL575P, AC103563.7, MAL, AC103563.2, AC103563.9, MRPS5, ZNF514, ZNF2, SLC2AXP1, AC092835.1, PROM2, KCNIP3, FABP7P2, FAHD2A, AC009238.3, AC009238.2, AC009238.1, UBTFL5, AC133104.2, AC133104.1, TRIM43B, AC009237.11, AC009237.1, AC009237.10, AC009237.2, TRIM64FP, AC009237.14, AC009237.3, AC009237.8, AC009237.15, AC009237.5, OR7E102P.
- chr5:58,198–5,078,311, 107 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:22,580,225–27,496,994, 54 genes, copy number 5–7: GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1.
- chr5:38,025,568–41,968,366, 60 genes, copy number 5–8 (within-gene range 4–8): LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6.
- chr6:61,574,328–62,286,225, 4 genes, copy number 5: MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1.
- chr6:72,316,599–73,828,316, 37 genes, copy number 14–27: AL035633.1, FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109.
- chr9:37,588,413–38,068,687, 1 gene, copy number 6 (within-gene range 2–6): AL138752.2.
- chr9:37,650,954–37,746,904, 1 gene, copy number 6 (within-gene range 2–6): FRMPD1.
- chr9:37,753,803–43,045,120, 149 genes, copy number 6 (broad region; genes not listed).
- chr11:23,520,322–27,722,058, 35 genes, copy number 7–32 (within-gene range 2–32): AC068472.1, LINC02726, AC100768.1, RNU6-783P, AC099842.1, LINC02686, Y_RNA, LUZP2, AC115990.1, AC087373.1, RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1, ANO3, AC021698.1, ANO3-AS1, AC079064.1, MUC15, SLC5A12, FIBIN, BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF.
- chr11:113,687,547–113,791,752, 10 genes, copy number 6: TMPRSS5, MTRF1LP1, ZW10, RPS29P19, AP003170.5, AP003170.4, CLDN25, ATF4P4, AP003170.2, LRRC37A13P.
- chr11:113,818,077–113,822,458, 2 genes, copy number 6: AP003170.3, AP003170.1.
- chr13:29,935,771–33,802,853, 70 genes, copy number 5–13 (broad region; genes not listed).
- chr13:33,829,539–33,829,649, 1 gene, copy number 5: RNU5A-4P.
- chr16:52,198,012–52,677,747, 11 genes, copy number 5: AC007333.2, AC007333.1, CASC22, TOX3, AC007490.1, CASC16, AC026462.5, AC026462.3, AC026462.2, AC026462.4, AC026462.1.
- chr17:30,059,052–34,272,242, 169 genes, copy number 5–53 (broad region; genes not listed).
- chr17:39,566,915–39,747,291, 12 genes, copy number 39: AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr18:7,566,782–8,406,861, 1 gene, copy number 5 (within-gene range 4–5): PTPRM.
- chr18:7,995,570–9,615,240, 38 genes, copy number 5 (within-gene range 4–5): U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, AP001531.1, AP005899.2, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1.
- chr18:10,297,299–15,330,282, 169 genes, copy number 5–11 (broad region; genes not listed).
- chr18:22,088,060–22,419,294, 11 genes, copy number 8: AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.
- chr20:34,194,569–64,313,132, 773 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,127. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
